TCGA case TCGA-FS-A1ZU — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: Essen. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7ce09a09-074e-4f38-bed7-98ab34347fbe

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 70 years; Vital status: Dead; Days to death: 808 days (2.2 years).

Diagnoses (4)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Classification of tumor: metastasis; Age at diagnosis: 72.3 years (26,400 days); Days to diagnosis: 544 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Timepoint category: Prior to Procurement.
   Recorded as not given: Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: V; Sites of involvement: Skin, Extremities; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 70.8 years (25,856 days); Year of diagnosis: 2002; AJCC staging edition: 5th; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 3 of this record; Age at diagnosis: 72.6 years (26,535 days); Days to diagnosis: 679 days (1.9 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 679 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 808 days (2.2 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FS-A1ZU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Initial weight: 130 mg.
  Slide TCGA-FS-A1ZU-06A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FS-A1ZU-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FS-A1ZU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 8.4; Radiation therapy to primary: No; Primary location: Distant Metastasis; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: Yes; Ifn treatment 90 days prior to resection: Yes.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities.

GDC annotations on this case (curator notes; quoted as recorded):
- Acceptable treatment for TCGA tumor: Patient received interferon for the specimen submitted to TCGA.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 808 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 808 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 679 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FS-A1ZU-06A-12D-A194-01): tumor purity 0.95, ploidy 3.45, whole-genome doublings 1.
